Gene-level copy-number profile of tumor specimen TCGA-XF-A9T6-01A from TCGA case TCGA-XF-A9T6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 88.2 years (32,207 days).
Specimen TCGA-XF-A9T6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.99a22e92-8d14-4518-858f-f29cb2008d5f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A9T6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/328ac813-f605-4a6e-a2e6-626de0719a3b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,173; copy number 2: 43,697; copy number 3: 6,405; copy number 4: 2,088; copy number 6: 40; copy number 7: 171; copy number 8: 149; copy number 9: 33; copy number 10: 29; copy number 12: 14; copy number 14: 8; copy number 21: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A9T6-01A-11D-A42D-01): tumor purity 0.83, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 454 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:10,759,350–12,885,211, 47 genes, copy number 9–12 (within-gene range 2–12): LINC00606, AC018495.1, SLC6A11, AC027128.1, SLC6A1, SLC6A1-AS1, AC066580.1, HRH1, AC083855.2, CHCHD4P4, ATG7, AC083855.1, AC026185.1, AC022001.1, VGLL4, AC022001.2, AC022001.3, TAMM41, FANCD2P2, CYCSP12, NUP210P2, MARK2P14, AC090958.1, RN7SL147P, SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17, CAND2, AC034198.2, RPL32, SNORA7A, AC034198.1, LINC02022.
- chr3:85,799,987–87,631,619, 18 genes, copy number 14–21: CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6.
- chr3:89,587,886–90,261,708, 6 genes, copy number 8: MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr8:95,204,456–95,811,254, 1 gene, copy number 7 (within-gene range 4–7): C8orf37-AS1.
- chr8:95,403,802–103,385,067, 175 genes, copy number 7–10 (broad region; genes not listed).
- chr8:123,226,189–123,541,206, 13 genes, copy number 6 (within-gene range 3–6): ZHX1-C8orf76, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32.
- chr11:93,661,682–104,252,651, 158 genes, copy number 8–10 (within-gene range 3–10) (broad region; genes not listed).
- chr13:19,262,797–19,536,762, 9 genes, copy number 10 (within-gene range 2–10): ANKRD26P3, MRPL3P1, LINC00421, PARP4P2, CCNQP3, AL356259.1, SLC25A15P2, TPTE2, CYCSP32.
- chr18:45,825,675–47,102,243, 27 genes, copy number 6 (within-gene range 1–6): SIGLEC15, EPG5, PSTPIP2, RN7SKP26, AC012569.1, RNY4P37, ATP5F1A, HAUS1, RNU6-1278P, C18orf25, RNF165, AC015959.1, AC018931.1, LOXHD1, ST8SIA5, AC090311.1, AC090241.2, AC090241.3, PIAS2, AC090241.1, AC090373.1, KATNAL2, ELOA3D, ELOA3C, ELOA3B, ELOA3, ELOA2.

Autosomal genes at a single copy (total copy number 1): 7,173. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
